Somatic mutation profile of tumor specimen TCGA-AR-A1AI-01A (aliquot TCGA-AR-A1AI-01A-11D-A12Q-09) from TCGA case TCGA-AR-A1AI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.2 years (17,229 days).
Specimen TCGA-AR-A1AI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b4ebaae-0a37-4599-a358-f2de09839c8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AI-10A (Blood Derived Normal), aliquot TCGA-AR-A1AI-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06a81540-39af-46f8-81dd-d2199a485717

The open-access MAF lists 74 somatic variants for this specimen: 60 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 55, Silent 14, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.808T>A p.F270I | Missense Mutation (SNP) | VAF 26/72 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519988, CM161002, COSV52691720, COSV52697968, COSV52744290; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTN4 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV99400670; called by muse, mutect2, varscan2
- ADCY3 | c.2654G>A p.R885Q | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1466209850, COSV53169052; called by muse, mutect2, varscan2
- ANAPC5 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs778284423, COSV55843415; called by muse, mutect2, varscan2
- ANKRD17 | c.5656C>T p.P1886S | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.223); catalogued as COSV58222960; called by muse, mutect2, varscan2
- ARHGEF3 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); catalogued as rs372602142; called by muse, mutect2, varscan2
- BCL9 | c.3612C>G p.F1204L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV99325747; called by muse, mutect2, varscan2
- BRCA2 | c.7006C>T p.R2336C | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs431825347, COSV66448051; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRIX1 | c.833G>C p.R278T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV57761205; called by muse, mutect2, varscan2
- CAMKV | c.1261G>C p.A421P | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.272); catalogued as COSV99615924; called by muse, mutect2, varscan2
- CDH12 | c.1745C>T p.T582I | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101203275, COSV101203483; called by muse, mutect2
- CDH18 | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99937774; called by muse, mutect2
- CDK19 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60450460; called by muse, mutect2, varscan2
- CDS1 | c.200G>C p.R67T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV55688701; called by muse, mutect2, varscan2
- CEP162 | c.3996A>T p.E1332D | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV100003309; called by muse, mutect2, varscan2
- CMC4 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as COSV62899761; called by muse, mutect2, varscan2
- CMYA5 | c.11571C>G p.I3857M | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV69745777; called by muse, mutect2, varscan2
- COL12A1 | c.1567A>C p.M523L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.945); catalogued as COSV59398894; called by muse, mutect2, varscan2
- CYP2A13 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as COSV57838543; called by muse, mutect2, varscan2
- DOCK11 | c.440A>T p.D147V | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52241688; called by muse, mutect2, varscan2
- DYNC1I1 | c.1500C>A p.D500E | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV61463948; called by muse, mutect2, varscan2
- IGHV3-7 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs369520613; called by muse, mutect2, varscan2
- IGSF10 | c.5840C>T p.S1947F | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56787060; called by muse, mutect2, varscan2
- LACTB2 | c.41G>C p.R14P | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52567751, COSV52568290; called by muse, mutect2, varscan2
- LPCAT1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.033); catalogued as COSV52039008; called by muse, varscan2
- MAP7D1 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV100294763; called by mutect2, varscan2
- MAPK10 | c.128C>T p.A43V (on ENST00000359221 / NM_001351625.2; = p.A81V on NM_002753.5) | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs143720396, COSV60378527; called by muse, mutect2, varscan2
- MPP2 | c.375+1G>T p.X125_splice (on ENST00000461854 / NM_001278372.2; = p.X101_splice on NM_005374.5) | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as COSV52236799; called by muse, mutect2, varscan2
- MYH7 | c.2487G>T p.W829C | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62520747; called by muse, mutect2, varscan2
- MYH7B | c.3927C>G p.I1309M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); catalogued as rs773772775, COSV99328835; called by muse, mutect2, varscan2
- NEURL4 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs755931561, COSV59750989; called by muse, mutect2
- NXPE3 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs200277463, COSV56290951; called by muse, mutect2, varscan2
- PCDHGA1 | c.1362G>T p.Q454H | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as COSV65297324; called by muse, mutect2, varscan2
- PDRG1 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV52431716; called by muse, mutect2, varscan2
- PDXDC1 | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 53/434 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57908467; called by muse, mutect2, varscan2
- PRKD1 | c.1756G>C p.D586H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV59574159; called by muse, mutect2, varscan2
- PSMD7 | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as rs1378525956, COSV54697918; called by muse, mutect2, varscan2
- RAG1 | c.2599G>A p.D867N | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs1022967472, COSV55026071; called by muse, mutect2, varscan2
- RFX6 | c.2653T>C p.C885R | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60586367; called by muse, mutect2, varscan2
- RIMS1 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.164); catalogued as rs1406553500, COSV53457232; called by muse, mutect2, varscan2
- SCN4A | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101438628; called by muse, mutect2, varscan2
- SENP6 | c.2135C>G p.S712C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100894615, COSV64190840; called by muse, varscan2
- SSMEM1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs189237675, COSV99927830; called by mutect2, varscan2
- SYNGAP1 | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.637); catalogued as COSV99538917; called by muse, mutect2, varscan2
- TAF1 | c.3601C>T p.R1201* (on ENST00000373790 / NM_138923.4; = p.R1222* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/224 reads (9%) | catalogued as COSV52112502; called by muse, mutect2
- TAF7 | c.539G>C p.R180P | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57665415; called by muse, mutect2, varscan2
- TAPT1 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1455132724, COSV58823781; called by muse, mutect2, varscan2
- TPTE2 | c.1402C>T p.P468S (on ENST00000400230 / NM_199254.2; = p.P391S on NM_130785.3) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55031383; called by muse, mutect2
- TRPM6 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1471268371, COSV62514488; called by muse, mutect2, varscan2
- TSR3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV50104298; called by muse, mutect2, varscan2
- UFL1 | c.2232G>C p.K744N | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.185); catalogued as COSV65150076; called by muse, mutect2, varscan2
- XPNPEP1 | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as COSV100451113; called by muse, mutect2
- ZDBF2 | c.5636del p.A1879Vfs*35 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as COSV65627342; called by mutect2, pindel, varscan2
- ZNF282 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.636); catalogued as rs1294301387, COSV100021852; called by muse, mutect2, varscan2
- ZNF330 | c.477T>A p.F159L | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as COSV53707662; called by muse, mutect2, varscan2
- ZNF420 | c.1287T>A p.N429K | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.572); catalogued as COSV100421479; called by muse, mutect2
- ZNF582 | c.695G>A p.C232Y | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56732835; called by muse, mutect2, varscan2
- ZNF675 | c.955A>C p.K319Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV63096408; called by muse, mutect2, varscan2
- TRAF3 | c.1520_1523del p.H507Rfs*21 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel
- TRBV4-2 | c.233G>C p.S78T | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANGEL2 | c.1161G>T p.R387= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV64737053; called by muse, mutect2, varscan2
- ARID5B | c.165G>C p.A55= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV54422998; called by muse, mutect2, varscan2
- CASP8AP2 | c.3789G>A p.K1263= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99387475; called by mutect2, varscan2
- COL1A2 | c.3273C>A p.P1091= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV51960454; called by muse, mutect2, varscan2
- DMXL2 | c.6966G>C p.V2322= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV51849189; called by muse, mutect2, varscan2
- DUOX2 | c.2985G>C p.L995= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV66532825; called by muse, mutect2, varscan2
- KIF27 | c.3351C>T p.F1117= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV52829555; called by muse, mutect2, varscan2
- LENG1 | c.354C>T p.G118= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs1341867392, COSV55364802; called by muse, mutect2, varscan2
- MC5R | c.684G>A p.A228= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV61253842; called by muse, mutect2, varscan2
- MRPL55 | c.31C>T p.L11= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV54342442; called by muse, mutect2
- OR7C1 | c.741G>T p.V247= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV99934953; called by muse, mutect2
- PCDHGA7 | c.1830G>A p.K610= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV53892085, COSV99545549; called by muse, mutect2, varscan2
- PKDREJ | c.4500T>G p.P1500= | Silent (SNP) | VAF 61/205 reads (30%) | catalogued as COSV53550217; called by muse, mutect2, varscan2
- USP32 | c.3273G>A p.L1091= | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as COSV56271149; called by muse, mutect2, varscan2
